Surgical pathology report (de-identified scan), TCGA case TCGA-CZ-5454, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site Harvard, specimen TCGA-CZ-5454-01A (Primary Tumor).

[page 1 of 3]
Accession Number: [REDACTED] Report Status: Amend/Addenda
Type: Surgical Pathology
Specimen Type: Kidney, partial or total resection
Procedure Date: [REDACTED]
Ordering Provider: [REDACTED]

CASE: [REDACTED]
PATIENT: [REDACTED]

TCGA-CZ-5454

***** Added Report *****

PATHOLOGIC DIAGNOSIS:

A. RIGHT NEPHRECTOMY (1670g):

RENAL CELL CARCINOMA, clear cell type, 15.1 cm,
Fuhrman nuclear grade II/IV.
Tumor is limited to kidney.

Vascular, ureteric, and soft tissue resection margins are negative for tumor.
Lymphovascular invasion is present but tumor does not involve the renal vein.

AJCC Classification (6th Edition): T2 N0 MX.

The non-neoplastic kidney will be evaluated by Renal Pathology, and the findings will be reported in an addendum.

B. INFRA-AORTIC VENA CAVAL LYMPH NODE:

Three (3) lymph nodes with expanded follicles and lipid-laden histiocytes within interfollicular areas; negative for tumor.

Immunoperoxidase studies performed on paraffin-embedded sections reveal a mixed population of CD3-positive/CD5-positive/CD43-positive T cells and CD20-positive B cells, with B cells predominating in follicles and T cells most concentrated in the interfollicular areas. The B cells are negative for CD5 and CD43. CD10 highlights B cells of the germinal centers. Bcl-2 is negative in the germinal center B cells and positive in T cells and B cells of the mantle zone. CD43 is expressed on T cells and plasma cells with no aberrant expression on B cells. The B cells and plasma cells appear to be polytypic for kappa and lambda light chain expression.

The overall findings are consistent with a reactive process.
Diagnostic features of a lymphoproliferative disorder are not seen.

This portion of the case was also reviewed by Dr. [REDACTED]
Hematopathology Service, who concurs.

CLINICAL DATA:

History: None given.

Operation: Right radical nephrectomy, regional lymph node dissection.

Operative Findings: None given.

Clinical Diagnosis: Right renal mass.

TISSUE SUBMITTED:

A/1. Right kidney-tissue bank.

B/2. Infra aorta vena cava lymph node.

GROSS DESCRIPTION:

The specimen is received fresh in two parts, each labeled with the patient's name and unit number.

Part A, "#1. Right kidney", consists of a 1670-gram right nephrectomy specimen (28.5 x 14.7 x 9.5 cm) to include a right kidney (21.0 x 9.9 x 5.5 cm), renal vein (1.1 cm in length x 0.9 cm diameter), renal artery (2.0 cm in length x 0.5 cm in diameter) and ureter (7.3 cm in length x 0.3 cm in diameter). The entire left side of the specimen is inked black and the specimen is bisected to reveal a single focally cystic tan/yellow to tan/pink, hemorrhagic mass (15.1 x 10.9 x 6.2 cm) located in the lower pole, abutting the kidney capsule with no gross evidence of invasion of the capsule. The mass comes to within 9.0 cm of the ureteric resection margin, 5.8 cm to the artery and 4.1 cm to the vein. There is no evidence of tumor extending into the vein, artery, ureter or perinephric

[page 2 of 3]
[REDACTED]

[REDACTED]

[REDACTED] TCGA - CZ - 5454

[page 3 of 3]
Accession Number: [REDACTED]

Type: Cytogenetics

Report Status: Final

CASE: [REDACTED]

PATIENT

Cytogeneticist: [REDACTED]

KARYOTYPE: K1:48,XY,add(1)(q21),psu dic (3;1)(p21;p11),+7,+20[5]
K2:46,XY K3: 46,XY[5]

METAPHASES COUNTED: 15

ANALYZED: 15

SCORED: 0

BANDING: GTG

INTERPRETATION:

Three different specimens were received and analyzed from this tumor.

All metaphases contained clonal aberrations including loss of the short arm of chromosome 3 which is a characteristic finding in renal cell carcinoma, clear cell type.

No cytogenetic aberrations were identified in metaphases analyzed from specimens T2 and T3.

COMMENTS:

Mosaicism and small chromosome anomalies may not be detectable using the standard methods employed. Chromosome analysis was performed at a level of 400 bands or greater.

INDICATION FOR TEST:

? RCC

[REDACTED]

Source: NCI Genomic Data Commons file 4fd36b1c-eac9-4756-b8e2-bd3576d2a4d4 (TCGA-CZ-5454.A4C7E861-89F5-4AC0-B4E2-0279BB56C81E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).